CCDI case PBCDCG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/373e53e1-46b2-4c27-8e58-79dee0984d4f

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Chordoma, NOS: ICD-O-3 morphology code: 9370/3; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 7.1 years (2,591 days).

Biospecimens (3 samples)
- Sample 0DP7LA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP7LH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DP7LK: Tissue type: Tumor; Specimen type: Solid Tissue.
